Somatic mutation profile of tumor specimen ALCH-B3GP-TTP1-A (aliquot ALCH-B3GP-TTP1-A-1-0-D-A80D-36) from ALCHEMIST case ALCH-B3GP, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 67.9 years (24,799 days).
Specimen ALCH-B3GP-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9758d827-96a8-4e67-ada6-e9c3cf12ba27.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3GP-NB1-A (Blood Derived Normal), aliquot ALCH-B3GP-NB1-A-1-0-D-A80D-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/58e6fbf7-67a1-42ab-a7c7-7e4e1fd166a8

The open-access MAF lists 156 somatic variants for this specimen: 95 protein-altering or splice-affecting, 38 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 79, Silent 38, Intron 9, 3'UTR 5, Nonsense Mutation 5, Frame Shift Del 5, Splice Region 3, RNA 3, 5'UTR 3, Nonstop Mutation 2, 3'Flank 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY8 | c.1993G>A p.E665K | Missense Mutation (SNP) | VAF 117/583 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.031); catalogued as COSV53895979; called by muse, mutect2, varscan2
- CALM3 | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.036); catalogued as rs1307420144, COSV52194689; called by muse, mutect2, varscan2
- CLEC4E | c.215G>A p.G72E | Missense Mutation (SNP) | VAF 45/173 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.031); catalogued as COSV100222565; called by muse, mutect2, varscan2
- COL3A1 | c.3088G>A p.G1030S | Missense Mutation (SNP) | VAF 91/640 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.344); catalogued as COSV58586147; called by muse, mutect2, varscan2
- CYLC2 | c.541G>T p.E181* | Nonsense Mutation (SNP) | VAF 10/55 reads (18%) | catalogued as rs751615596, COSV66336737, COSV66337270; called by muse, mutect2, varscan2
- DOLK | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.024); catalogued as COSV65364268; called by muse, mutect2, varscan2
- EDC4 | c.1773G>C p.K591N | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.145); catalogued as COSV62766451; called by muse, mutect2, varscan2
- FAM83H | c.3343G>A p.E1115K | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as rs1435785864; called by muse, mutect2, varscan2
- FOXO4 | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs766209807, COSV58575550; called by muse, mutect2, varscan2
- HELLS | c.284A>G p.K95R | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV53296082; called by muse, mutect2, varscan2
- KIAA0408 | c.1742C>T p.S581F | Missense Mutation (SNP) | VAF 21/316 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV64105844; called by muse, mutect2
- LIG3 | c.2053G>A p.A685T | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.186); catalogued as COSV52008671; called by muse, mutect2
- MRFAP1L1 | c.109G>T p.E37* | Nonsense Mutation (SNP) | VAF 17/89 reads (19%) | catalogued as rs751499970; called by mutect2, varscan2
- NEGR1 | c.671C>T p.A224V | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.412); catalogued as COSV60846409; called by muse, mutect2, varscan2
- NTRK2 | c.826C>G p.Q276E | Missense Mutation (SNP) | VAF 84/614 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV52872475; called by muse, mutect2, varscan2
- OR2T12 | c.171G>A p.M57I | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs760401833, COSV58779684; called by muse, mutect2, varscan2
- OR8D1 | c.174del p.M59Cfs*25 | Frame Shift Del (DEL) | VAF 28/138 reads (20%) | catalogued as COSV63442288; called by mutect2, pindel, varscan2
- PLEC | c.5698G>A p.E1900K (on ENST00000322810 / NM_201380.4; = p.E1790K on NM_000445.5) | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs1257910796; called by muse, mutect2, varscan2
- PLXNA2 | c.585C>A p.F195L | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV65442156; called by muse, mutect2, varscan2
- RB1 | c.1330C>T p.Q444* | Nonsense Mutation (SNP) | VAF 64/308 reads (21%) | catalogued as CD942296, CM030503, COSV57315141; called by muse, mutect2, varscan2
- RBCK1 | c.1219G>C p.E407Q (on ENST00000356286 / NM_031229.4; = p.E365Q on NM_006462.6) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.309); catalogued as COSV62292868; called by muse, mutect2, varscan2
- REV3L | c.4439T>C p.I1480T | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.039); catalogued as rs748427642; called by muse, mutect2, varscan2
- ROBO4 | c.1400G>T p.R467L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV100127322; called by muse, mutect2, varscan2
- RYR3 | c.10045C>G p.R3349G (on ENST00000389232; = p.R3350G on NM_001036.6) | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV66800715; called by muse, mutect2
- SLC36A1 | c.1430A>G p.*477Wext*117 | Nonstop Mutation (SNP) | VAF 6/18 reads (33%) | catalogued as rs1449065514, COSV54653168; called by muse, mutect2, varscan2
- SLFN5 | c.1516G>A p.V506I | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs760908289, COSV55482929; called by muse, mutect2, varscan2
- SNRPA | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs540507848; called by muse, mutect2, varscan2
- SSPN | c.673T>C p.Y225H | Missense Mutation (SNP) | VAF 51/176 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.314); catalogued as rs541896000; called by muse, mutect2, varscan2
- SSX5 | c.247G>A p.D83N (on ENST00000347757 / NM_175723.1; = p.D124N on NM_021015.4) | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.282); catalogued as rs1556925349; called by muse, mutect2
- STKLD1 | c.1604G>A p.G535D | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64241283; called by muse, mutect2, varscan2
- TMC2 | c.2305T>A p.F769I | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV99082068; called by muse, mutect2, varscan2
- TMEM183A | c.943C>T p.L315= | Splice Region (SNP) | VAF 20/90 reads (22%) | catalogued as COSV65887990; called by muse, mutect2
- TP53 | c.461del p.G154Afs*16 | Frame Shift Del (DEL) | VAF 12/35 reads (34%) | catalogued as CM951223, COSV52667239, COSV52783646, COSV53625267; called by mutect2, pindel, varscan2
- XYLT1 | c.931G>A p.V311M | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs780997015, COSV99763090; called by muse, mutect2
- ZNF34 | c.1069C>T p.H357Y | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100603382; called by muse, mutect2, varscan2
- ZNF530 | c.1696A>C p.K566Q | Missense Mutation (SNP) | VAF 22/173 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV60531900; called by mutect2, varscan2
- ZNF695 | c.1043G>A p.G348E | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs1305105984, COSV60584758; called by muse, mutect2, varscan2
- ACOT1 | c.401T>C p.V134A | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, varscan2
- ACTL7A | c.1223C>G p.S408* | Nonsense Mutation (SNP) | VAF 14/61 reads (23%) | called by muse, mutect2, varscan2
- ADAMTS17 | c.3013G>C p.G1005R | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AKAP9 | c.7515del p.Y2506Tfs*13 (on ENST00000359028; = p.Y2482Tfs*13 on NM_005751.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 24/144 reads (17%) | called by mutect2, pindel, varscan2
- ALG10 | c.499T>C p.C167R | Missense Mutation (SNP) | VAF 89/600 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); called by muse, mutect2, varscan2
- ALPK1 | c.997G>C p.E333Q | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- AMPD1 | c.1244T>A p.V415E | Missense Mutation (SNP) | VAF 66/371 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ATP1A4 | c.1851T>G p.I617M | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AXIN1 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- C1orf198 | c.169G>T p.E57* | Nonsense Mutation (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2, varscan2
- CEP120 | c.2012A>T p.Q671L | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.112); called by mutect2, varscan2
- CFAP47 | c.4187A>G p.N1396S | Missense Mutation (SNP) | VAF 52/150 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- CHRM4 | c.612C>A p.F204L | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- COL4A4 | c.4897G>C p.E1633Q | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSTB | c.262A>G p.N88D | Missense Mutation (SNP) | VAF 55/297 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- DACT1 | c.1438C>G p.Q480E | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- EDEM1 | c.1450G>C p.D484H | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- EIF2AK4 | c.2708G>T p.G903V | Missense Mutation (SNP) | VAF 33/240 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM114A1 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 30/179 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- FAM169B | n.434+1G>A | Splice Site (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2, varscan2
- FER1L6 | c.1357A>T p.N453Y | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- FZD8 | c.746A>G p.Y249C | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- GALNT2 | c.1556G>C p.R519T | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- GINS4 | c.655G>T p.A219S | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- GNPTAB | c.571+7T>A | Splice Region (SNP) | VAF 19/109 reads (17%) | called by muse, varscan2
- HDHD5-AS1 | n.440G>A | Splice Region (SNP) | VAF 35/182 reads (19%) | called by muse, mutect2, varscan2
- KBTBD4 | c.937C>G p.P313A | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- KIR3DL3 | c.477del p.I160Sfs*26 | Frame Shift Del (DEL) | VAF 18/124 reads (15%) | called by mutect2, pindel, varscan2
- LRRC7 | c.4186C>G p.P1396A (on ENST00000651989 / NM_001370785.2; = p.P1316A on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/196 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- MOK | c.538A>T p.T180S | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MS4A7 | c.187G>A p.G63R | Missense Mutation (SNP) | VAF 32/206 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NHS | c.526C>G p.R176G | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NIPBL | c.8122A>G p.M2708V | Missense Mutation (SNP) | VAF 42/347 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- NLRP13 | c.476G>C p.G159A | Missense Mutation (SNP) | VAF 38/257 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- NPC1L1 | c.1792G>C p.E598Q | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- OBSCN | c.21766G>A p.E7256K | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR2AJ1 | c.508G>A p.G170S | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- PGBD2 | c.634G>T p.V212L | Missense Mutation (SNP) | VAF 44/192 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PI4KB | c.730G>A p.E244K (on ENST00000368873 / NM_001369623.1; = p.E256K on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.164); called by muse, mutect2
- PLAG1 | c.921G>A p.M307I | Missense Mutation (SNP) | VAF 35/349 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRAME | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.749); called by muse, mutect2, varscan2
- PTH2R | c.165A>G p.*55Wext*14 | Nonstop Mutation (SNP) | VAF 16/100 reads (16%) | called by muse, mutect2, varscan2
- PUF60 | c.861G>A p.M287I (on ENST00000526683 / NM_001362896.2; = p.M270I on NM_014281.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- SALL3 | c.1785A>T p.K595N | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.063); called by mutect2, varscan2
- SAMD9L | c.2678A>G p.K893R | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SMAP1 | c.1397G>C p.W466S (on ENST00000370455 / NM_001044305.3; = p.W439S on NM_021940.5) | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SPATA5L1 | c.1025G>C p.G342A | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- SRARP | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- SYNE2 | c.15453del p.W5151Cfs*8 | Frame Shift Del (DEL) | VAF 44/247 reads (18%) | called by mutect2, pindel, varscan2
- TENM1 | c.895A>G p.T299A | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.605); called by muse, mutect2, varscan2
- UNC79 | c.1696G>A p.D566N (on ENST00000393151 / NM_001346218.2; = p.D389N on NM_020818.5) | Missense Mutation (SNP) | VAF 39/235 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- VEZF1 | c.901A>G p.I301V | Missense Mutation (SNP) | VAF 46/253 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- WEE2 | c.1553A>G p.Q518R | Missense Mutation (SNP) | VAF 46/263 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZCCHC10 | c.454G>T p.A152S (on ENST00000509437 / NM_001300818.3; = p.A130S on NM_017665.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/262 reads (20%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZDBF2 | c.691C>G p.P231A | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.045); called by muse, mutect2
- ZNF10 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.346); called by muse, varscan2
- ZNF668 | c.1076C>G p.S359C | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ZNF677 | c.477C>A p.F159L | Missense Mutation (SNP) | VAF 31/187 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ADAMTS18 | c.1227C>A p.P409= | Silent (SNP) | VAF 60/309 reads (19%) | catalogued as rs751159225; called by muse, mutect2, varscan2
- AL645922.1 | c.1002G>A p.K334= | Silent (SNP) | VAF 18/204 reads (9%) | catalogued as rs991691148; called by muse, mutect2
- ANAPC5 | c.972G>T p.L324= | Silent (SNP) | VAF 11/70 reads (16%) | called by muse, mutect2, varscan2
- AP1G2 | c.891C>T p.I297= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as COSV55338686; called by muse, mutect2, varscan2
- ASPM | c.5724T>C p.F1908= | Silent (SNP) | VAF 99/591 reads (17%) | called by muse, mutect2, varscan2
- AXL | c.237G>C p.A79= | Silent (SNP) | VAF 20/100 reads (20%) | called by muse, mutect2, varscan2
- BRINP3 | c.2041C>A p.R681= | Silent (SNP) | VAF 34/165 reads (21%) | catalogued as rs199983605, COSV66532306, COSV66534597; called by muse, mutect2, varscan2
- C12orf56 | c.1290G>C p.L430= (on ENST00000543942 / NM_001170633.2; = p.L270= on NM_001099676.3) | Silent (SNP) | VAF 28/130 reads (22%) | called by muse, varscan2
- CALHM6 | c.501G>A p.L167= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs1562326635; called by muse, mutect2, varscan2
- CCDC39 | c.1494T>C p.C498= | Silent (SNP) | VAF 118/511 reads (23%) | called by muse, mutect2, varscan2
- CHST6 | c.90G>A p.G30= | Silent (SNP) | VAF 3/13 reads (23%) | called by muse, mutect2
- CLIP3 | c.861C>T p.L287= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs369876691, COSV62112462; called by muse, mutect2, varscan2
- CNTN3 | c.2523G>T p.R841= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as COSV55164807, COSV99723784; called by muse, mutect2, varscan2
- DLGAP3 | c.825G>A p.A275= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as rs756223853; called by muse, mutect2, varscan2
- DNAH5 | c.3648C>G p.V1216= | Silent (SNP) | VAF 15/143 reads (10%) | catalogued as COSV99454849; called by muse, mutect2
- DNAH7 | c.9693G>C p.L3231= | Silent (SNP) | VAF 54/267 reads (20%) | called by muse, mutect2, varscan2
- DOCK1 | c.873A>G p.K291= | Silent (SNP) | VAF 20/83 reads (24%) | called by muse, mutect2, varscan2
- ENOX2 | c.1473G>A p.Q491= (on ENST00000338144 / NM_001382520.1; = p.Q462= on NM_006375.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 43/101 reads (43%) | called by muse, mutect2, varscan2
- FAM104B | c.324G>A p.Q108= | Silent (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- FER1L6 | c.1356A>T p.S452= | Silent (SNP) | VAF 15/90 reads (17%) | called by muse, varscan2
- GPC5 | c.366C>A p.T122= | Silent (SNP) | VAF 24/78 reads (31%) | called by muse, mutect2, varscan2
- GSTP1 | c.300C>G p.L100= | Silent (SNP) | VAF 22/109 reads (20%) | called by muse, mutect2
- INSC | c.445C>A p.R149= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as COSV101088897; called by muse, mutect2, varscan2
- JMJD1C | c.6666C>A p.L2222= | Silent (SNP) | VAF 38/236 reads (16%) | called by muse, varscan2
- MON1A | c.43C>T p.L15= | Silent (SNP) | VAF 5/77 reads (6%) | called by muse, mutect2
- OR10J5 | c.378C>T p.I126= | Silent (SNP) | VAF 18/90 reads (20%) | catalogued as rs1429471971; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.1839G>A p.G613= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs772236501; called by muse, mutect2, varscan2
- RNF123 | c.1314C>T p.I438= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as rs528256688, COSV59692405; called by muse, mutect2, varscan2
- RYR2 | c.1635T>A p.R545= | Silent (SNP) | VAF 55/245 reads (22%) | called by muse, mutect2, varscan2
- SCNN1B | c.378C>T p.I126= | Silent (SNP) | VAF 30/121 reads (25%) | called by muse, mutect2, varscan2
- SNAP91 | c.1473T>A p.P491= | Silent (SNP) | VAF 5/26 reads (19%) | called by mutect2, varscan2
- SPSB4 | c.93C>T p.P31= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs1425570931; called by muse, mutect2, varscan2
- ST3GAL1 | c.27G>A p.L9= | Silent (SNP) | VAF 3/18 reads (17%) | called by muse, mutect2
- TAF4 | c.129C>G p.L43= | Silent (SNP) | VAF 5/11 reads (45%) | called by mutect2, varscan2
- TASOR2 | c.2784A>G p.E928= | Silent (SNP) | VAF 7/31 reads (23%) | called by muse, varscan2
- TBC1D25 | c.804C>G p.L268= | Silent (SNP) | VAF 24/51 reads (47%) | called by muse, mutect2, varscan2
- TRAFD1 | c.423A>G p.E141= | Silent (SNP) | VAF 33/128 reads (26%) | called by muse, mutect2, varscan2
- TRBV30 | c.300C>G p.L100= | Silent (SNP) | VAF 6/25 reads (24%) | called by muse, mutect2
- AC026410.1 | n.492C>T | RNA (SNP) | VAF 11/23 reads (48%) | called by muse, mutect2, varscan2
- ARMCX4 | c.1038+3998G>C | Intron (SNP) | VAF 6/8 reads (75%) | called by muse, mutect2, varscan2
- BSG | chr19:571519 C>A | 5'Flank (SNP) | VAF 17/63 reads (27%) | called by muse, mutect2, varscan2
- CACNA1G | c.*326C>T | 3'UTR (SNP) | VAF 80/229 reads (35%) | catalogued as rs756668063; called by muse, mutect2, varscan2
- CPS1 | c.*36del | 3'UTR (DEL) | VAF 47/400 reads (12%) | called by mutect2, pindel, varscan2
- CUL7 | c.-198C>T | 5'UTR (SNP) | VAF 7/49 reads (14%) | called by mutect2, varscan2
- DHRS4 | chr14:23970125 G>C | 3'Flank (SNP) | VAF 13/84 reads (15%) | called by muse, mutect2, varscan2
- ECPAS | c.22+11C>T | Intron (SNP) | VAF 3/15 reads (20%) | called by muse, varscan2
- GNG13 | c.*34G>C | 3'UTR (SNP) | VAF 19/66 reads (29%) | catalogued as COSV99241905, COSV99243664; called by muse, mutect2, varscan2
- H2AZ2 | chr7:44823204 C>T | 3'Flank (SNP) | VAF 16/91 reads (18%) | called by muse, mutect2, varscan2
- HBA1 | c.301-10C>G | Intron (SNP) | VAF 9/47 reads (19%) | called by muse, mutect2, varscan2
- NDUFS2 | c.95+21C>G | Intron (SNP) | VAF 16/155 reads (10%) | called by muse, mutect2, varscan2
- NECTIN1 | c.79+14657C>G | Intron (SNP) | VAF 13/63 reads (21%) | called by muse, mutect2, varscan2
- POLR3B | c.2817+10C>T | Intron (SNP) | VAF 70/308 reads (23%) | called by muse, mutect2, varscan2
- PTGER3 | c.*93T>A | 3'UTR (SNP) | VAF 68/362 reads (19%) | catalogued as COSV100656457; called by muse, mutect2, varscan2
- PTHLH | c.-96G>T | 5'UTR (SNP) | VAF 39/115 reads (34%) | called by muse, mutect2, varscan2
- RBM4B | c.*50T>C | 3'UTR (SNP) | VAF 25/117 reads (21%) | called by muse, mutect2, varscan2
- RNF217-AS1 | n.3831C>G | RNA (SNP) | VAF 18/178 reads (10%) | called by muse, mutect2, varscan2
- RNF217-AS1 | n.3157C>T | RNA (SNP) | VAF 7/38 reads (18%) | called by muse, mutect2, varscan2
- SWAP70 | c.240+9132C>G | Intron (SNP) | VAF 46/288 reads (16%) | called by muse, mutect2, varscan2
- TYR | c.-16G>A | 5'UTR (SNP) | VAF 29/180 reads (16%) | called by muse, mutect2, varscan2
- ZDHHC11 | c.784+54G>A | Intron (SNP) | VAF 7/93 reads (8%) | catalogued as rs1463601480; called by muse, mutect2
- ZEB2 | c.73+5348C>A | Intron (SNP) | VAF 38/325 reads (12%) | catalogued as rs1274834039; called by muse, mutect2, varscan2
